Somatic mutation profile of tumor specimen TCGA-2J-AAB4-01A (aliquot TCGA-2J-AAB4-01A-12D-A40W-08) from TCGA case TCGA-2J-AAB4, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Overlapping lesion of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 48.7 years (17,794 days).
Specimen TCGA-2J-AAB4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ecca4c8-29ac-469d-94b3-1f684f9f9907.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AAB4-10A (Blood Derived Normal), aliquot TCGA-2J-AAB4-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e07abcd8-1f2a-4115-b9ac-e8fa368a7cb1

The open-access MAF lists 36 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 9, Frame Shift Del 2, Nonsense Mutation 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 22/217 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376T>A p.Y126N | Missense Mutation (SNP) | VAF 20/103 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886039483, CM118879, COSV52661802, COSV52809424, COSV53031989, COSV53515469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC10 | c.3280C>T p.R1094C (on ENST00000372530 / NM_001198934.2; = p.R1066C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770561160, COSV99766425; called by muse, mutect2, varscan2
- ABCG1 | c.881A>G p.Q294R | Missense Mutation (SNP) | VAF 133/1046 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100493730; called by muse, mutect2, varscan2
- ACAP2 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 109/853 reads (13%) | catalogued as COSV100461273; called by muse, mutect2, varscan2
- ADAMTS15 | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 237/976 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs776875002, COSV100143021; called by muse, mutect2, varscan2
- ADAMTS9 | c.5425C>T p.R1809W | Missense Mutation (SNP) | VAF 88/511 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767643539, COSV99898462; called by muse, mutect2, varscan2
- DNAH3 | c.3223C>T p.R1075C | Missense Mutation (SNP) | VAF 53/395 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); catalogued as rs541368919, COSV54529378; called by muse, mutect2, varscan2
- DNER | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.023); catalogued as rs767590493, COSV59159659; called by muse, mutect2, varscan2
- GABBR1 | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.264); catalogued as rs752173788, COSV63542179; called by muse, mutect2, varscan2
- MARCHF5 | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 50/391 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs765703589, COSV100739473; called by muse, mutect2, varscan2
- MEFV | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 96/572 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1022125045, COSV99560133; called by muse, mutect2, varscan2
- NTNG1 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 45/408 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as rs939752168, COSV53962757; called by muse, mutect2, varscan2
- PPP4R2 | c.115A>G p.M39V | Missense Mutation (SNP) | VAF 79/574 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs150423598; called by muse, mutect2, varscan2
- SYNE1 | c.22122A>G p.I7374M (on ENST00000367255 / NM_182961.4; = p.I7303M on NM_033071.3) | Missense Mutation (SNP) | VAF 218/1500 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.701); catalogued as rs1397713388, COSV99550272; called by muse, mutect2, varscan2
- SYT4 | c.436A>T p.T146S | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99673140; called by muse, mutect2, varscan2
- URI1 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV100368744; called by muse, mutect2
- USP34 | c.7874C>T p.S2625F | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV101276533; called by muse, mutect2, varscan2
- VSTM4 | c.155G>C p.R52T | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100039058; called by muse, mutect2
- WDR48 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 83/502 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs770433005, COSV100072900; called by muse, mutect2, varscan2
- ZNF345 | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 61/414 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV100080099, COSV59322638; called by muse, mutect2, varscan2
- ZNF506 | c.875A>G p.K292R | Missense Mutation (SNP) | VAF 49/340 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV101475601; called by muse, mutect2, varscan2
- ATG2B | c.4865A>G p.Y1622C | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GANAB | c.1140_1145del p.S381_L382del | In Frame Del (DEL) | VAF 88/651 reads (14%) | called by mutect2, pindel, varscan2
- SEC61B | c.248_255del p.S83Yfs*57 | Frame Shift Del (DEL) | VAF 90/832 reads (11%) | called by mutect2, pindel
- SMAD4 | c.678del p.S227Vfs*14 | Frame Shift Del (DEL) | VAF 31/191 reads (16%) | called by mutect2, pindel, varscan2
- AL121899.2 | c.114G>T p.A38= | Silent (SNP) | VAF 78/580 reads (13%) | catalogued as COSV101198360; called by muse, mutect2, varscan2
- CASKIN1 | c.4212G>A p.A1404= | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as rs369309592; called by muse, mutect2, varscan2
- CXCL12 | c.69C>T p.P23= | Silent (SNP) | VAF 102/731 reads (14%) | catalogued as rs778458592, COSV59107262; called by muse, mutect2, varscan2
- GK | c.813G>A p.V271= (on ENST00000427190 / NM_001205019.2; = p.V265= on NM_000167.6) | Silent (SNP) | VAF 69/221 reads (31%) | catalogued as COSV100970733; called by muse, mutect2, varscan2
- HECW1 | c.4077C>T p.D1359= | Silent (SNP) | VAF 54/541 reads (10%) | catalogued as rs780958494, COSV67837496; called by muse, mutect2, varscan2
- KCNV2 | c.453C>T p.F151= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs758516182, COSV66057335; called by muse, mutect2
- PSG1 | c.24C>T p.P8= | Silent (SNP) | VAF 98/574 reads (17%) | catalogued as rs746519084, COSV54947258; called by muse, mutect2, varscan2
- RASGEF1A | c.453T>C p.C151= | Silent (SNP) | VAF 13/123 reads (11%) | catalogued as COSV100988617; called by muse, mutect2
- ZP3 | c.546C>T p.N182= (on ENST00000394857 / NM_001110354.2; = p.N131= on NM_007155.6) | Silent (SNP) | VAF 55/327 reads (17%) | catalogued as rs371699247, COSV100334403; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827846 A>C | 3'Flank (SNP) | VAF 84/203 reads (41%) | catalogued as COSV100157261; called by muse, mutect2, varscan2
